Somatic mutation profile of tumor specimen TARGET-10-PARDST-09A (aliquot TARGET-10-PARDST-09A-01D) from TARGET case TARGET-10-PARDST, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (2,011 days).
Specimen TARGET-10-PARDST-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4de0a56d-89f9-46ee-ab8d-169ec90c351c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARDST-10A (Blood Derived Normal), aliquot TARGET-10-PARDST-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/711dc525-16cb-4f9a-8213-78a60864864d

The open-access MAF lists 164 somatic variants for this specimen: 105 protein-altering or splice-affecting, 20 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 20, Intron 19, Nonsense Mutation 15, 3'UTR 10, 5'UTR 4, RNA 3, 5'Flank 2, Splice Region 2, Splice Site 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD2 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1553368998; called by muse, mutect2, varscan2
- ARHGEF11 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs755958507, COSV63810131; called by muse, mutect2, varscan2
- BRIP1 | c.702G>C p.K234N | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99371412; called by muse, mutect2, varscan2
- CREB3 | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99043135; called by muse, varscan2
- CREB3 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as rs750100528; called by muse, varscan2
- FAM184A | c.1130C>G p.S377* | Nonsense Mutation (SNP) | VAF 26/106 reads (25%) | catalogued as COSV58853272; called by muse, mutect2, varscan2
- FAT3 | c.4414G>A p.D1472N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53113497; called by muse, mutect2, varscan2
- GMIP | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs373620612; called by muse, mutect2, varscan2
- GON4L | c.3727C>A p.Q1243K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.159); catalogued as COSV55187758; called by muse, mutect2, varscan2
- GPR1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.19); catalogued as COSV67976874; called by muse, mutect2, varscan2
- GRID2 | c.1699C>T p.L567F | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.019); catalogued as rs199616654; called by muse, mutect2, varscan2
- LARP1B | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as rs1343171236; called by muse, mutect2, varscan2
- MMUT | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.788); catalogued as rs768467805, COSV51277077; called by muse, mutect2, varscan2
- NLRP10 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1182450950; called by muse, mutect2, varscan2
- OR13C9 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV52241137; called by muse, varscan2
- OR13C9 | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs375372646, COSV99403526; called by muse, varscan2
- PCDHAC2 | c.2158C>G p.L720V | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53846051; called by muse, mutect2
- PCDHGA7 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.066); catalogued as COSV53892315; called by muse, mutect2
- PCLO | c.2150C>T p.S717L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV61632014, COSV61641626; called by mutect2, varscan2
- PIK3CD | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV63129695; called by muse, mutect2, varscan2
- RBM23 | c.708C>G p.I236M (on ENST00000359890 / NM_001077351.2; = p.I220M on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs889957649, COSV57128730; called by muse, mutect2, varscan2
- RNF144B | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.557); catalogued as rs1213638936, COSV99464962; called by muse, mutect2
- SCN3A | c.1466C>G p.S489* | Nonsense Mutation (SNP) | VAF 10/170 reads (6%) | catalogued as COSV51813854; called by muse, mutect2
- SHTN1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.458); catalogued as rs765922322; called by muse, mutect2, varscan2
- SRRM2 | c.4660C>T p.Q1554* | Nonsense Mutation (SNP) | VAF 31/99 reads (31%) | catalogued as COSV100070500; called by muse, mutect2, varscan2
- STK39 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs780458695; called by muse, mutect2, varscan2
- TLR10 | c.1461C>G p.F487L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV58300462; called by muse, mutect2
- TTBK1 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV99443960; called by muse, mutect2, varscan2
- VCAM1 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.282); catalogued as COSV54120121; called by muse, mutect2, varscan2
- VIT | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs1187955847; called by muse, mutect2, varscan2
- WDR17 | c.3735G>C p.K1245N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.08); catalogued as rs754271078, COSV54578738; called by muse, mutect2, varscan2
- WDR81 | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs1410136583; called by muse, mutect2, varscan2
- WDR81 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as rs1350909497; called by muse, mutect2
- ZNF521 | c.1091C>G p.S364* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV64132490; called by muse, mutect2
- ZZEF1 | c.4255G>C p.E1419Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV67556442; called by muse, mutect2, varscan2
- AK9 | c.4999G>C p.E1667Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ARL4A | c.417G>T p.R139S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ATP2B1 | c.3595G>C p.E1199Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ATRIP | c.814C>G p.L272V | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.04); called by muse, mutect2
- ATXN1L | c.1390C>G p.H464D | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ATXN7L1 | c.1153_1154insCCCC p.K385Tfs*18 | Frame Shift Ins (INS) | VAF 22/42 reads (52%) | called by mutect2, pindel, varscan2
- BSPRY | c.421C>T p.Q141* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- C11orf95 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CA5B | c.60G>C p.W20C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CALD1 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- CFAP65 | c.580C>G p.Q194E | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- CLUAP1 | c.492G>C p.L164F | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- CREB3 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- CROT | c.361C>G p.Q121E | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CX3CR1 | c.663C>G p.C221W | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DSEL | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEA1 | c.1735C>G p.Q579E | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- FBXO30 | c.1882C>G p.L628V | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- GARRE1 | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GARRE1 | c.2822G>A p.R941K | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- GBA2 | c.2225C>G p.S742C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- GON4L | c.6700C>G p.L2234V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GON4L | c.1971G>C p.K657N | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, varscan2
- GON4L | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | called by muse, varscan2
- GPR155 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- GZMH | c.452C>G p.S151* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- HBP1 | c.245C>G p.S82* | Nonsense Mutation (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- HOXB5 | c.27C>G p.F9L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- IGHV5-51 | chr14:106578734 TCACTGTGTGTCT>GTC | Missense Mutation (DEL) | VAF 28/32 reads (88%) | called by pindel, varscan2*
- IGKV2-24 | chr2:89176326 TGAGGAAATT>GGTTGGGG | Missense Mutation (DEL) | VAF 32/39 reads (82%) | called by pindel, varscan2*
- IPO8 | c.1372C>G p.L458V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- KEL | c.1314+7G>C | Splice Region (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- KIDINS220 | c.1099-1G>A p.X367_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- KMO | c.182G>C p.R61T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRAS | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT78 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2
- LDHC | c.665C>G p.S222* | Nonsense Mutation (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- LINC00687 | n.713G>C | Splice Region (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- LRRTM3 | c.867G>C p.K289N | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGI2 | c.1664C>G p.S555* | Nonsense Mutation (SNP) | VAF 25/51 reads (49%) | called by muse, mutect2, varscan2
- MAST4 | c.1916C>G p.T639R (on ENST00000403625 / NM_001164664.2; = p.T450R on NM_015183.3) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MPEG1 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MROH5 | c.3666G>C p.W1222C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NF1 | c.8047G>T p.G2683* (on ENST00000358273 / NM_001042492.3; = p.G2662* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- NOSTRIN | c.587C>G p.S196C (on ENST00000317647 / NM_001039724.4; = p.S118C on NM_052946.3) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- NRXN1 | c.2899G>C p.D967H | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP155 | c.2254G>A p.E752K (on ENST00000231498 / NM_153485.3; = p.E693K on NM_004298.4) | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- OR5V1 | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDLIM5 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 32/76 reads (42%) | called by muse, varscan2
- PLA2R1 | c.702G>C p.E234D | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- POP1 | c.1954C>G p.Q652E | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PROX1 | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- RNF225 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SATB2 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STT3A | c.1923G>C p.K641N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THBS1 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TLN2 | c.4705G>C p.E1569Q | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM268 | c.367C>G p.Q123E | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.359); called by muse, mutect2
- TRAM2 | c.1071G>C p.E357D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- TUSC1 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2
- USF3 | c.4949C>G p.S1650C | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- USF3 | c.4603C>G p.Q1535E | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- UTRN | c.7438C>G p.Q2480E | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- VPS13B | c.4939G>A p.E1647K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.664); called by muse, mutect2
- WDR81 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZFHX4 | c.5128C>T p.Q1710* | Nonsense Mutation (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- ZNF131 | c.957G>C p.K319N (on ENST00000509156 / NM_001330707.2; = p.K285N on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZNF430 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- ZNF718 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ZSCAN23 | c.364G>C p.V122L | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- APLP2 | c.2022C>T p.L674= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- BMP3 | c.69G>A p.E23= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99261367; called by muse, mutect2, varscan2
- CDH22 | c.570G>T p.V190= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV64837010; called by muse, mutect2, varscan2
- CKAP4 | c.324C>G p.L108= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- ENO4 | c.435C>T p.H145= (on ENST00000622726; = p.H144= on NM_001242699.2) | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs768385505; called by muse, mutect2, varscan2
- HCN4 | c.1491C>T p.L497= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1260804406; ClinVar: likely benign; called by muse, mutect2, varscan2
- LCE1A | c.189G>A p.G63= | Silent (SNP) | VAF 7/27 reads (26%) | called by mutect2, varscan2
- MYO6 | c.2730C>T p.L910= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV100889384; called by muse, mutect2, varscan2
- NFIB | c.24C>T p.L8= | Silent (SNP) | VAF 25/73 reads (34%) | called by muse, mutect2, varscan2
- NME1-NME2 | c.318G>A p.L106= (on ENST00000555572; = p.L81= on NM_001018136.3) | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV99184020; called by muse, mutect2, varscan2
- NPFFR2 | c.1203C>T p.Y401= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as rs538543232, COSV100440247, COSV58146856, COSV58152388; called by muse, mutect2, varscan2
- NRXN1 | c.3054G>A p.R1018= | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- OR2L3 | c.285G>A p.G95= | Silent (SNP) | VAF 8/193 reads (4%) | catalogued as COSV63455827, COSV63455873; called by muse, mutect2
- PLA2R1 | c.3897C>T p.L1299= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as rs1407546544; called by muse, mutect2, varscan2
- SEC22C | c.492G>A p.V164= | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- STAB2 | c.4692C>T p.G1564= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs200367145, COSV66335342; called by muse, mutect2, varscan2
- TENM3 | c.3849C>G p.L1283= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs749365911; called by muse, mutect2, varscan2
- TRAF1 | c.1158C>G p.L386= | Silent (SNP) | VAF 22/54 reads (41%) | called by muse, mutect2, varscan2
- TULP3 | c.651C>T p.L217= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs759054606; called by muse, mutect2, varscan2
- WDR81 | c.909G>C p.L303= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as rs1398433929; called by muse, mutect2, varscan2
- AC073310.1 | n.632G>C | RNA (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- ADH5P5 | chr5:23979970 G>A | 5'Flank (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- AL139327.1 | n.233G>A | RNA (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- ATG2A | chr11:64892786 C>G | 3'Flank (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- CENATAC | c.*79C>T | 3'UTR (SNP) | VAF 14/39 reads (36%) | catalogued as rs1450796586; called by muse, mutect2, varscan2
- FER | c.1924+4873C>G | Intron (SNP) | VAF 5/124 reads (4%) | called by muse, mutect2
- FEZ1 | c.-294G>C | 5'UTR (SNP) | VAF 10/35 reads (29%) | catalogued as rs979442204; called by muse, mutect2, varscan2
- GON4L | c.1788+92G>C | Intron (SNP) | VAF 33/78 reads (42%) | catalogued as rs763988210; called by muse, mutect2, varscan2
- HMBOX1 | c.*373C>G | 3'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- HMBOX1 | c.*622G>C | 3'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- HYDIN2 | n.13672G>C | RNA (SNP) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- IL2RA | c.*137G>A | 3'UTR (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2
- IL36B | c.261+835C>G | Intron (SNP) | VAF 10/22 reads (45%) | called by muse, varscan2
- LAMA2 | c.*17C>A | 3'UTR (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- LARGE1 | c.788-4318G>C | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- LMX1A | c.-22-39G>T | Intron (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- MAD2L1 | c.-36G>A | 5'UTR (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- MAP4K1 | c.1447-44C>G | Intron (SNP) | VAF 11/31 reads (35%) | catalogued as rs371529081; called by muse, mutect2, varscan2
- MEI1 | c.*70G>A | 3'UTR (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- METTL14 | c.-73C>G | 5'UTR (SNP) | VAF 17/62 reads (27%) | catalogued as COSV101183435; called by muse, mutect2, varscan2
- MOCS1 | c.124-91C>G | Intron (SNP) | VAF 27/78 reads (35%) | catalogued as COSV57934457; called by muse, mutect2, varscan2
- MRPS27 | c.592-68G>C | Intron (SNP) | VAF 14/60 reads (23%) | called by muse, varscan2
- NPHP1 | c.1926+433G>A | Intron (SNP) | VAF 43/73 reads (59%) | catalogued as rs757316427; called by muse, mutect2, varscan2
- PGRMC2 | c.*124G>C | 3'UTR (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2
- PPP1R1C | c.*6+114C>G | Intron (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- REPS2 | c.*136C>A | 3'UTR (SNP) | VAF 25/28 reads (89%) | called by muse, mutect2, varscan2
- RIC8B | c.*103G>C | 3'UTR (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2
- RPL23 | c.14-223C>T | Intron (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- SGIP1 | c.74+2583C>G | Intron (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- SLC13A1 | c.661-1260G>A | Intron (SNP) | VAF 6/94 reads (6%) | catalogued as rs1271702241; called by muse, mutect2
- SLC30A5 | c.274-32G>A | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- SPRED1 | c.-1G>C | 5'UTR (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- STXBP2 | c.87+81C>G | Intron (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- SWI5 | chr9:128275403 C>T | 5'Flank (SNP) | VAF 11/129 reads (9%) | called by muse, mutect2
- TNS3 | c.724-4606C>G | Intron (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- TSPAN31 | c.*1178C>T | 3'UTR (SNP) | VAF 3/12 reads (25%) | catalogued as rs1323224963; called by muse, mutect2
- WEE2 | c.759-65G>A | Intron (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3394+870G>A | Intron (SNP) | VAF 10/14 reads (71%) | called by muse, varscan2
- ZNF717 | c.184+102G>C | Intron (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
